Somatic mutation profile of tumor specimen 0DR9C2 from CCDI case PBCFPI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.0 years (2,550 days).
Specimen 0DR9C2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b8c1942-6886-41a0-a240-766a053b8cae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f0c31e7-563c-4ad0-911f-fc6cb74c7b87

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, In Frame Del 2, Nonsense Mutation 1, 5'UTR 1, Intron 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.2060_2063del p.V687Afs*35 | Frame Shift Del (DEL) | VAF 198/1817 reads (11%) | catalogued as rs1324968782; called by mutect2, pindel
- ARHGAP10 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 726/1662 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs777388291, COSV60607473; called by muse, varscan2
- FMN2 | c.4464G>T p.M1488I | Missense Mutation (SNP) | VAF 614/1588 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV100147434; called by muse, mutect2, varscan2
- HUNK | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 55/1044 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765995957; called by muse, mutect2
- IGSF23 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 206/1752 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.794); catalogued as rs918738344, COSV68806887; called by muse, mutect2, varscan2
- KCTD16 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 873/2024 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs773343153, COSV72577989; called by muse, mutect2, varscan2
- LRRK1 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 532/1275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200335851, COSV99437928; called by muse, mutect2, varscan2
- MARK2 | c.2306C>T p.S769L (on ENST00000402010 / NM_001039469.2; = p.S705L on NM_004954.5) | Missense Mutation (SNP) | VAF 738/1744 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56850642; called by muse, mutect2, varscan2
- PAQR7 | c.764_766del p.F255del | In Frame Del (DEL) | VAF 508/1282 reads (40%) | catalogued as rs752557686; called by pindel, varscan2
- RBM17 | c.930+2T>C p.X310_splice | Splice Site (SNP) | VAF 402/997 reads (40%) | catalogued as COSV65915089; called by muse, mutect2, varscan2
- SLC39A10 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 172/3666 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs778580688, COSV62767732; called by muse, mutect2
- ZNF385B | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 154/3245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375494558, COSV100416545; called by muse, mutect2
- ACE2 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 477/615 reads (78%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLF7 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 866/2119 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MCOLN2 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 780/1711 reads (46%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1650_1652del p.S551del | In Frame Del (DEL) | VAF 323/912 reads (35%) | called by pindel, varscan2
- SCN3B | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 259/1305 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TOGARAM1 | c.5008G>A p.A1670T | Missense Mutation (SNP) | VAF 642/1564 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- USP15 | c.494T>G p.I165R | Missense Mutation (SNP) | VAF 386/969 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 80/2554 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- GAL3ST3 | c.822G>A p.S274= | Silent (SNP) | VAF 390/790 reads (49%) | catalogued as rs1334416587, COSV61749585; called by muse, mutect2, varscan2
- JMY | c.960C>T p.Y320= | Silent (SNP) | VAF 149/1312 reads (11%) | called by muse, mutect2, varscan2
- OR10G6 | c.138G>A p.A46= | Silent (SNP) | VAF 172/1360 reads (13%) | catalogued as rs542782655; called by muse, mutect2, varscan2
- XIRP1 | c.5031G>C p.S1677= | Silent (SNP) | VAF 175/1481 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.354C>T p.N118= | Silent (SNP) | VAF 183/2214 reads (8%) | catalogued as rs1293253104, COSV57636856; called by muse, mutect2
- GNB2 | c.-45C>A | 5'UTR (SNP) | VAF 118/269 reads (44%) | called by muse, mutect2, varscan2
- OR4P4 | c.*22G>A | 3'UTR (SNP) | VAF 547/629 reads (87%) | catalogued as rs765339777, COSV58921654; called by muse, mutect2, varscan2
- PITRM1 | c.56+72C>A | Intron (SNP) | VAF 123/261 reads (47%) | called by muse, mutect2, varscan2
